Gene-level copy-number profile of tumor specimen C3L-06339-01 from CPTAC case C3L-06339, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.4 years (22,077 days).
Specimen C3L-06339-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1c7b20e3-8f46-4e35-b326-3e066c863eb4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06339-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/1e3e5a25-a7ad-4732-acd3-f4b0b4675331

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 3,498; copy number 2: 27,942; copy number 3: 18,108; copy number 4: 8,381; copy number 5: 796; copy number 6: 24; copy number 8: 11.

Homozygous deletions (total copy number 0; autosomes only): 143 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:100,804–969,090, 16 genes: AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1.
- chr9:10,532,145–14,722,733, 41 genes (within-gene range 0–1): AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1.
- chr9:19,895,800–25,089,151, 86 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 831 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:7,356,203–19,146,253, 127 genes, copy number 5 (broad region; genes not listed).
- chr7:62,275,361–62,275,678, 1 gene, copy number 6: AC128676.1.
- chr7:76,818,377–97,437,896, 254 genes, copy number 5 (broad region; genes not listed).
- chr7:103,074,881–127,253,093, 297 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:152,435,695–152,757,951, 10 genes, copy number 5 (within-gene range 4–5): FABP5P3, CCT8L1P, LINC01003, AC104843.2, 5S_rRNA, AC104843.1, AC003109.1, XRCC2, ATP5PBP3, RN7SL845P.
- chr9:26,746,953–26,796,304, 2 genes, copy number 5: AL451137.2, AL451137.1.
- chr9:42,725,013–43,045,120, 11 genes, copy number 8: BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1.
- chr9:63,817,748–68,540,883, 91 genes, copy number 5 (broad region; genes not listed).
- chr9:137,434,364–138,253,217, 23 genes, copy number 6 (within-gene range 3–6): ENTPD8, NSMF, MIR7114, PNPLA7, MRPL41, DPH7, ZMYND19, ARRDC1, AL590627.2, ARRDC1-AS1, EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602, AL772363.1, CACNA1B, AL591424.1, IL9RP1, TUBBP5, AL591424.2, AL954642.1, FAM157B.
- chr10:38,783,004–42,495,337, 10 genes, copy number 5: AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839.
- chr16:46,469,341–46,569,097, 1 gene, copy number 5 (within-gene range 3–5): ANKRD26P1.
- chr21:12,999,676–13,113,790, 4 genes, copy number 5: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P.

Autosomal genes at a single copy (total copy number 1): 652. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
